Somatic mutation profile of tumor specimen TCGA-D7-5579-01A (aliquot TCGA-D7-5579-01A-01D-1600-08) from TCGA case TCGA-D7-5579, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.4 years (27,175 days).
Specimen TCGA-D7-5579-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fc7d422-2711-4250-8262-2b9621fb7186.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-5579-10A (Blood Derived Normal), aliquot TCGA-D7-5579-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eb6eafa-f4ff-445f-aaf0-d8f46039e567

The open-access MAF lists 152 somatic variants for this specimen: 120 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 28, Nonsense Mutation 6, Splice Region 3, Intron 2, RNA 2, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KNSTRN | c.35T>G p.V12G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.17); PolyPhen benign (0.04); catalogued as COSV51103821; called by muse, mutect2, varscan2
- TP53 | c.375G>C p.T125= | Splice Region (SNP) | VAF 24/94 reads (26%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA1 | c.4464A>G p.Q1488= | Splice Region (SNP) | VAF 9/121 reads (7%) | catalogued as COSV66071035; called by muse, mutect2
- ABI3BP | c.2203A>C p.T735P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.375); catalogued as COSV52552294; called by muse, mutect2, varscan2
- ADA | c.695A>T p.K232M | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV63069177; called by muse, varscan2
- ADAMTS12 | c.1724A>G p.K575R | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV61260128, COSV61272004; called by muse, mutect2, varscan2
- ADCY6 | c.2279A>G p.N760S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs753426236, COSV57170739; called by muse, mutect2, varscan2
- AGBL5 | c.2638C>A p.L880M | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.206); catalogued as COSV64080854; called by muse, mutect2, varscan2
- AKTIP | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs755048837, COSV50889584; called by muse, mutect2, varscan2
- ALDH1A3 | c.544T>G p.F182V | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747235458, COSV60903415; called by muse, mutect2, varscan2
- ANKRD11 | c.3766C>T p.H1256Y | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.023); catalogued as COSV56372770; called by muse, mutect2, varscan2
- ANO3 | c.836A>C p.Y279S | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs767545047, COSV56809705; called by muse, mutect2, varscan2
- ANXA10 | c.917C>A p.S306* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV63740558; called by muse, mutect2
- ASTN2 | c.2744C>A p.T915N (on ENST00000313400 / NM_001365069.1; = p.T864N on NM_014010.5) | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV57819514; called by muse, mutect2, varscan2
- ATG7 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as COSV61615909; called by muse, mutect2
- C7orf25 | c.1199T>A p.L400H | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63273104, COSV63274413; called by muse, mutect2, varscan2
- CACNA1S | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62944083; called by muse, mutect2, varscan2
- CACNB2 | c.626G>T p.G209V (on ENST00000324631 / NM_201596.3; = p.G154V on NM_000724.4) | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV56648750; called by muse, mutect2
- CAPN7 | c.2395T>A p.L799M | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53746838; called by muse, mutect2, varscan2
- CCT8L2 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV63461767, COSV63463898; called by muse, mutect2, varscan2
- CD300LD | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV64710977; called by muse, mutect2, varscan2
- CD63 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as rs756637406, COSV57677489; called by muse, mutect2
- CEP85 | c.982A>G p.S328G | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV53332737; called by muse, mutect2, varscan2
- CHD1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1264385586, COSV52344994; called by muse, mutect2, varscan2
- CLEC7A | c.676T>C p.S226P (on ENST00000304084 / NM_197947.3; = p.S180P on NM_022570.5) | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV53723999; called by muse, mutect2, varscan2
- CNGA4 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66005440; called by muse, mutect2
- COG6 | c.1360G>C p.A454P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV62998129; called by muse, mutect2, varscan2
- DDX41 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV57254529; called by muse, mutect2, varscan2
- DISP3 | c.3977C>T p.T1326M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779449261, COSV53837267; called by mutect2, varscan2
- DNM3 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62458839, COSV62467892; called by muse, mutect2
- EIF3G | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205961593, COSV53460272; called by muse, mutect2, varscan2
- EIF4G1 | c.3953G>A p.G1318E (on ENST00000346169 / NM_198241.3; = p.G1123E on NM_004953.5) | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59994406; called by muse, mutect2, varscan2
- FCAMR | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61368349; called by muse, mutect2
- FERD3L | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as COSV51761976, COSV51764624; called by muse, mutect2, varscan2
- FRA10AC1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100784737; called by muse, mutect2
- GIGYF1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs568108210, COSV51947087; called by muse, mutect2, varscan2
- GOLGA4 | c.3236A>G p.K1079R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV62714084; called by muse, mutect2, varscan2
- IL13RA2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs782749009, COSV54567739; called by muse, mutect2, varscan2
- KIF1A | c.3806G>A p.R1269Q (on ENST00000320389 / NM_001379639.1; = p.R1261Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs753620726, COSV57502608; called by muse, mutect2
- LEF1 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.426); catalogued as COSV54473699; called by muse, mutect2, varscan2
- LHCGR | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV54303599; called by muse, mutect2, varscan2
- LNPEP | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV51481619; called by muse, mutect2, varscan2
- LRRK2 | c.6569C>T p.T2190I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV54172201; called by muse, mutect2
- MPEG1 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs755776015, COSV57095406; called by muse, mutect2, varscan2
- MSH3 | c.2447A>G p.E816G | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV54165472; called by muse, mutect2, varscan2
- MTHFR | c.1738T>C p.F580L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs770471347, COSV57172545, COSV57174644; called by muse, mutect2
- MUC17 | c.9938C>A p.T3313N | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60304426; called by muse, mutect2, varscan2
- NAGA | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV67170364; called by muse, mutect2
- NCOA3 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV59073841; called by muse, mutect2
- NEBL | c.2612A>T p.E871V | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV65806125; called by muse, mutect2, varscan2
- NFATC2IP | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770684941, COSV57911389; called by muse, mutect2, varscan2
- NLRP8 | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 68/359 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as COSV52594424; called by muse, mutect2, varscan2
- NOL4 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as rs960826327, COSV52341789; called by muse, mutect2, varscan2
- NPR1 | c.2602C>A p.Q868K | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as rs1285054809, COSV64118190; called by muse, mutect2, varscan2
- NRXN3 | c.1138T>G p.F380V (on ENST00000335750 / NM_001330195.2; = p.F7V on NM_004796.6) | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.938); catalogued as COSV59715637; called by muse, mutect2, varscan2
- NSD1 | c.7391G>A p.R2464H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs587784216, COSV61774851; ClinVar: benign; called by muse, mutect2
- NTRK2 | c.1492C>T p.P498S (on ENST00000323115 / NM_001369534.1; = p.P514S on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.874); catalogued as COSV52884017, COSV99453896; called by muse, mutect2, varscan2
- OR10J1 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as COSV71128971; called by muse, mutect2, varscan2
- OR2T6 | c.830T>G p.F277C | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63217125; called by muse, mutect2, varscan2
- OR4K15 | c.248T>G p.M83R (on ENST00000305051; = p.M59R on NM_001005486.1) | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100520979, COSV59303572; called by muse, mutect2, varscan2
- OR52K1 | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV56904857; called by muse, mutect2, varscan2
- OR6T1 | c.947T>G p.L316R | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs776524687, COSV58306488, COSV58309678; called by muse, mutect2, varscan2
- OSBPL6 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51931293; called by muse, mutect2, varscan2
- PALD1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs140490112; called by muse, mutect2, varscan2
- PARP6 | c.1859T>C p.M620T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV53003164; called by muse, mutect2, varscan2
- PDS5A | c.713C>G p.T238S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as COSV57831745; called by muse, mutect2, varscan2
- PDZRN4 | c.2387A>C p.K796T (on ENST00000402685 / NM_001164595.2; = p.K538T on NM_013377.4) | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54213825; called by muse, mutect2, varscan2
- PGLS | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as rs756046118, COSV53115524; called by muse, mutect2
- PIEZO2 | c.7544A>G p.Q2515R | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1386371498, COSV53294703; called by muse, mutect2, varscan2
- PLEC | c.9041C>T p.T3014M (on ENST00000322810 / NM_201380.4; = p.T2904M on NM_000445.5) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201565643; ClinVar: uncertain significance; called by muse, mutect2
- POTEE | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.478); catalogued as rs748017694, COSV100388449, COSV58239217; called by muse, mutect2, varscan2
- PRKACB | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65761254; called by muse, mutect2, varscan2
- PSG6 | c.64+1G>T p.X22_splice | Splice Site (SNP) | VAF 27/252 reads (11%) | catalogued as rs1222638985, COSV99413404; called by muse, mutect2, varscan2
- RASAL2 | c.428A>C p.E143A | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV62713387, COSV62724111; called by muse, mutect2
- RBFOX1 | c.269C>G p.T90R | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV60984967; called by muse, mutect2, varscan2
- RNF220 | c.458T>A p.L153* | Nonsense Mutation (SNP) | VAF 11/185 reads (6%) | catalogued as COSV62410054; called by muse, mutect2
- RPS6KA6 | c.1757C>A p.A586E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV53127330; called by muse, mutect2, varscan2
- RUSC1 | c.2567C>G p.T856S (on ENST00000368352 / NM_001105203.2; = p.T387S on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV52742975; called by muse, mutect2
- SGCA | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769778891, COSV56251217; ClinVar: uncertain significance; called by mutect2, varscan2
- SH2D4A | c.513A>C p.R171= | Splice Region (SNP) | VAF 9/82 reads (11%) | catalogued as COSV56125022; called by muse, mutect2, varscan2
- SHANK2 | c.1976T>C p.F659S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1288574452, COSV53620353; called by muse, mutect2
- SIGLEC1 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs754492228, COSV52473641; called by muse, mutect2
- SPTBN4 | c.5668C>T p.Q1890* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as COSV58959493; called by muse, mutect2
- STON1 | c.1845T>G p.I615M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.482); catalogued as COSV59138756; called by muse, mutect2, varscan2
- SULT1E1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs753982089, COSV56946944; called by muse, mutect2
- SYNE1 | c.2642A>T p.K881M (on ENST00000367255 / NM_182961.4; = p.K888M on NM_033071.3) | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55112063; called by muse, mutect2, varscan2
- SYNE2 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV59971516; called by muse, mutect2, varscan2
- TFDP3 | c.347T>C p.M116T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.45); catalogued as COSV59538678; called by muse, mutect2, varscan2
- TM6SF2 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777516403, COSV99364081; called by muse, mutect2, varscan2
- TMEM63B | c.1268T>G p.L423R | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52482624; called by muse, mutect2
- TMPRSS11F | c.1196A>C p.D399A | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV62469747; called by muse, mutect2, varscan2
- TNXB | c.8302G>A p.E2768K (on ENST00000647633; = p.E2521K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.702); catalogued as rs1053476236, COSV64489420; called by muse, mutect2, varscan2
- TOMM40 | c.950C>G p.S317C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); catalogued as COSV52986625, COSV99376250; called by muse, mutect2, varscan2
- TTC12 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as rs147647661; called by muse, mutect2, varscan2
- TTN | c.34223A>C p.K11408T (on ENST00000591111; = p.K10481T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | PolyPhen benign (0.313); catalogued as COSV60368298; called by muse, mutect2
- TTN | c.3712A>C p.T1238P (on ENST00000591111; = p.T1192P on NM_003319.4) | Missense Mutation (SNP) | VAF 20/172 reads (12%) | PolyPhen possibly damaging (0.603); catalogued as COSV60368316; called by muse, mutect2, varscan2
- ULK2 | c.2366G>A p.S789N | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV64448747; called by muse, mutect2, varscan2
- USH2A | c.7073T>A p.L2358H | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56442489; called by muse, mutect2, varscan2
- VPS13A | c.6341G>A p.R2114Q | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs367713644; called by muse, mutect2, varscan2
- WDR33 | c.2627G>A p.G876D | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV59245899; called by muse, mutect2, varscan2
- WDR38 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV62019481, COSV62019496; called by muse, mutect2, varscan2
- XCR1 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV58570840; called by muse, mutect2
- XIRP2 | c.9813A>C p.K3271N (on ENST00000628543; = p.K3446N on NM_152381.6) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV54736440; called by muse, mutect2, varscan2
- ZNF592 | c.2610C>G p.F870L | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55439820; called by muse, mutect2
- ZNF831 | c.4656A>C p.R1552S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV64045585; called by muse, mutect2, varscan2
- AADACL3 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ABCA5 | c.3234dup p.I1079Yfs*50 | Frame Shift Ins (INS) | VAF 22/97 reads (23%) | called by mutect2, pindel, varscan2
- ATG7 | c.1802G>A p.G601D | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.606); called by muse, mutect2
- CACNB2 | c.549G>T p.R183S (on ENST00000324631 / NM_201596.3; = p.R128S on NM_000724.4) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CNNM4 | c.695T>G p.I232S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EIF3F | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.166); called by muse, mutect2
- FMR1 | c.157_163del p.V53Ifs*5 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- IGSF9 | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, mutect2
- LIPF | c.110dup p.M38Dfs*10 | Frame Shift Ins (INS) | VAF 15/130 reads (12%) | called by mutect2, pindel, varscan2
- PKP3 | c.2199del p.I734Sfs*66 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- REV3L | c.6963C>G p.I2321M | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- SEMA3E | c.867A>T p.K289N | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE2NL | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ZSCAN26 | c.1243_1263del p.I415_P421del (on ENST00000623276 / NM_001111039.2; = p.I281_P287del on NM_152736.5) | In Frame Del (DEL) | VAF 6/80 reads (8%) | called by mutect2, pindel
- ANGPT1 | c.660A>G p.Q220= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV52439307; called by muse, mutect2, varscan2
- ARHGAP35 | c.1692T>C p.A564= | Silent (SNP) | VAF 11/283 reads (4%) | catalogued as COSV68335904; called by muse, mutect2
- ASIC4 | c.27C>T p.I9= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs144007748; called by muse, mutect2
- ATP10B | c.3027A>G p.G1009= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV59165410; called by muse, mutect2
- BRDT | c.2352G>A p.T784= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1374006867, COSV62866069; called by muse, mutect2, varscan2
- C19orf47 | c.1167G>T p.L389= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV63511378; called by muse, mutect2, varscan2
- CAMK1 | c.264G>T p.G88= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV56540522; called by muse, mutect2, varscan2
- CBX5 | c.114A>C p.L38= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV52938952; called by muse, mutect2
- CBY2 | c.549C>T p.R183= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1186574596, COSV60120016; called by muse, mutect2, varscan2
- COL6A3 | c.5778G>A p.T1926= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs555406717, COSV55111646; ClinVar: uncertain significance; called by muse, mutect2
- CYP7A1 | c.1014A>G p.A338= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as rs1434478772, COSV56966003; called by muse, mutect2, varscan2
- GABRA4 | c.450G>A p.K150= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV51935591; called by muse, mutect2
- KRTAP15-1 | c.198T>G p.T66= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV61878158; called by muse, mutect2, varscan2
- MCTP1 | c.817T>C p.L273= | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV56534711; called by muse, mutect2, varscan2
- NEUROD4 | c.12T>G p.T4= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV54471636; called by muse, mutect2, varscan2
- OR6C2 | c.330T>C p.F110= | Silent (SNP) | VAF 23/252 reads (9%) | catalogued as COSV59517057; called by muse, mutect2
- PPFIA2 | c.2629A>C p.R877= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV61028713, COSV61056585; called by muse, mutect2, varscan2
- PRAMEF19 | c.903T>G p.T301= | Silent (SNP) | VAF 28/200 reads (14%) | called by muse, mutect2, varscan2
- RLF | c.4959G>A p.G1653= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as COSV65653301; called by muse, mutect2, varscan2
- SCN2A | c.1800C>A p.T600= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs1451402785, COSV51856274; called by muse, mutect2, varscan2
- SENP7 | c.1956T>G p.S652= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV58620310; called by muse, mutect2, varscan2
- SERPINA3 | c.294G>A p.E98= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV101261692, COSV67587234; called by muse, mutect2, varscan2
- SLFN12 | c.321G>C p.V107= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV59227795; called by muse, mutect2, varscan2
- SPTA1 | c.3762A>G p.P1254= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV63760092; called by muse, mutect2, varscan2
- SUPT16H | c.195C>T p.I65= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV53528111; called by muse, mutect2, varscan2
- TRIM71 | c.1440C>T p.S480= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs753096691, COSV67472820; called by muse, mutect2
- TWNK | c.531T>C p.D177= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as COSV52972328; called by muse, mutect2, varscan2
- ZMYM6 | c.2085C>T p.P695= | Silent (SNP) | VAF 26/237 reads (11%) | catalogued as rs371144527; called by muse, mutect2, varscan2
- DCHS2 | n.7461C>A | RNA (SNP) | VAF 35/172 reads (20%) | catalogued as COSV61780413; called by muse, mutect2, varscan2
- KIF16B | c.3498+3115C>A | Intron (SNP) | VAF 23/198 reads (12%) | catalogued as COSV100734618; called by muse, mutect2, varscan2
- NR2C2 | c.72+583G>T | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- ZNF658B | n.2116T>G | RNA (SNP) | VAF 50/1212 reads (4%) | called by muse, mutect2
